Somatic mutation profile of tumor specimen TCGA-FB-AAPP-01A (aliquot TCGA-FB-AAPP-01A-12D-A40W-08) from TCGA case TCGA-FB-AAPP, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 71.8 years (26,239 days).
Specimen TCGA-FB-AAPP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de3f7f52-207b-43ac-a749-23ad6b039d93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-AAPP-11A (Solid Tissue Normal), aliquot TCGA-FB-AAPP-11A-11D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6acfe709-5744-4d55-bb64-35102d835167

The open-access MAF lists 114 somatic variants for this specimen: 87 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 25, Frame Shift Ins 3, Nonsense Mutation 3, RNA 2, Splice Region 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 460/478 reads (96%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP1B | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 267/563 reads (47%) | catalogued as rs1554054831, COSV99701578; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTL7A | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 141/331 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758729154, COSV61776227; called by muse, mutect2, varscan2
- ACTL7B | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 184/382 reads (48%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.922); catalogued as rs770928741, COSV65928446; called by muse, mutect2, varscan2
- ADAM29 | c.1063A>C p.I355L | Missense Mutation (SNP) | VAF 134/629 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.229); catalogued as COSV100821856; called by muse, mutect2, varscan2
- ADGRG7 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 142/618 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs779730760, COSV56293432; called by muse, mutect2, varscan2
- ADGRL2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 73/304 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54655701; called by muse, mutect2, varscan2
- ADRA2C | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs1397954852, COSV57466811; called by muse, mutect2
- ARHGAP32 | c.3986A>G p.N1329S (on ENST00000310343 / NM_001378025.1; = p.N980S on NM_014715.4) | Missense Mutation (SNP) | VAF 38/547 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1190436313, COSV100086514; called by muse, mutect2
- ASTN2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 95/269 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs777574038, COSV57811894; called by muse, mutect2, varscan2
- ATP2A1 | c.2942A>C p.D981A | Missense Mutation (SNP) | VAF 190/414 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100706747; called by muse, mutect2, varscan2
- BMP5 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs755749791, COSV100895661; called by muse, mutect2
- CASR | c.1814C>T p.P605L (on ENST00000490131; = p.P682L on NM_000388.4) | Missense Mutation (SNP) | VAF 107/417 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); catalogued as rs1553768989, CM102309, COSV56137331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC33 | c.1358C>A p.A453D | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV99173185; called by muse, mutect2
- CDH9 | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 28/517 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.665); catalogued as rs746982767, COSV50253245, COSV50524504; called by muse, mutect2
- CEACAM8 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 243/542 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs200797632, COSV99747336; called by muse, mutect2, varscan2
- CEMIP | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 99/448 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs368282778; called by muse, mutect2, varscan2
- CLEC14A | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 266/536 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.651); catalogued as rs777358442, COSV60563521; called by muse, mutect2, varscan2
- CLSTN1 | c.1328C>T p.P443L (on ENST00000377298 / NM_001009566.3; = p.P433L on NM_014944.4) | Missense Mutation (SNP) | VAF 157/724 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100790425, COSV63649988; called by muse, mutect2, varscan2
- COL6A2 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764497780, COSV55999809; called by muse, mutect2, varscan2
- CSMD1 | c.2155T>C p.S719P (on ENST00000520002; = p.S718P on NM_033225.6) | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100141741; called by muse, mutect2, varscan2
- CSPG5 | c.1135A>T p.S379C | Missense Mutation (SNP) | VAF 57/1069 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV99273548; called by muse, mutect2
- CUL7 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747949153, COSV99537547; called by muse, mutect2, varscan2
- CYLC1 | c.884G>T p.S295I | Missense Mutation (SNP) | VAF 102/143 reads (71%) | SIFT tolerated (0.13); PolyPhen benign (0.329); catalogued as COSV100253855; called by muse, mutect2, varscan2
- DEFB126 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 46/992 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs368122573; called by muse, mutect2
- DHX37 | c.2884G>A p.D962N | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs140554912; called by muse, mutect2, varscan2
- DSCAML1 | c.3238C>T p.R1080W (on ENST00000321322; = p.R1020W on NM_020693.4) | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1034319646, COSV58386656; called by muse, mutect2
- EDA2R | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 191/213 reads (90%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.684); catalogued as rs192316556, COSV53629949; called by muse, mutect2, varscan2
- EML4 | c.1949T>A p.I650K | Missense Mutation (SNP) | VAF 202/475 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100580569; called by muse, mutect2, varscan2
- EPHB3 | c.2438G>A p.R813Q | Missense Mutation (SNP) | VAF 127/245 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781335594, COSV100382708; called by muse, mutect2, varscan2
- FLACC1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs142397497; called by muse, mutect2, varscan2
- FMN2 | c.2990T>C p.I997T | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); catalogued as COSV100141957; called by muse, mutect2
- GPR12 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs758632134, COSV67343989; called by muse, mutect2, varscan2
- GREB1 | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs368329579; called by muse, mutect2, varscan2
- HEPACAM | c.575G>T p.R192I | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100005368; called by muse, mutect2, varscan2
- HIVEP1 | c.3794G>A p.R1265H | Missense Mutation (SNP) | VAF 205/447 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368115054; called by muse, mutect2, varscan2
- HOXD3 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.151); catalogued as rs750084616, COSV99979809; called by muse, varscan2
- IAPP | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 249/527 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.138); catalogued as COSV53714347, COSV99556939; called by muse, mutect2, varscan2
- IL1RN | c.224C>T p.P75L (on ENST00000409930 / NM_173842.3; = p.P57L on NM_000577.5) | Missense Mutation (SNP) | VAF 57/322 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99381336; called by muse, mutect2, varscan2
- IRF8 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310226478, COSV99235939; called by muse, mutect2
- ITGB6 | c.2173G>A p.V725I | Missense Mutation (SNP) | VAF 27/390 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV99323995; called by muse, mutect2
- JMJD7-PLA2G4B | c.3020G>A p.R1007Q | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs773261998, COSV100310375; called by muse, mutect2
- KDM4C | c.955A>G p.M319V | Missense Mutation (SNP) | VAF 200/409 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1345992659, COSV101184605; called by muse, mutect2, varscan2
- KLKB1 | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 50/475 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.093); catalogued as rs1413913327, COSV99249492; called by muse, mutect2
- LMAN1L | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.184); catalogued as rs774853977, COSV100547501; called by muse, varscan2
- LRP1 | c.8269G>A p.D2757N | Missense Mutation (SNP) | VAF 23/794 reads (3%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as rs1359956433, COSV99673808; called by muse, mutect2
- MAML1 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 113/727 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs199501746, COSV99482807; called by muse, mutect2, varscan2
- MCM6 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 170/332 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs142938887; called by muse, mutect2, varscan2
- MTOR | c.2657G>A p.R886H | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs376873727; called by muse, mutect2, varscan2
- MUC3A | c.9231G>A p.L3077= | Splice Region (SNP) | VAF 35/339 reads (10%) | catalogued as COSV60219221; called by muse, mutect2, varscan2
- NCAPD3 | c.3416G>T p.S1139I | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV101594444; called by muse, mutect2
- NIBAN1 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 56/580 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756094383, COSV62282789; called by muse, mutect2
- OR6K3 | c.557G>A p.G186E (on ENST00000368146; = p.G170E on NM_001005327.2) | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100933817; called by muse, mutect2
- OSBPL7 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99136488; called by muse, mutect2
- PABPC5 | c.790A>T p.I264F | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.243); catalogued as COSV100442029; called by muse, mutect2, varscan2
- PCDHB7 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 37/518 reads (7%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.005); catalogued as COSV99175175, COSV99177408; called by muse, mutect2
- PFKP | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475442390, COSV99828078; called by muse, mutect2
- PSMG3 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 49/479 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99365792; called by muse, mutect2, varscan2
- RNF43 | c.182_183del p.L61Qfs*13 | Frame Shift Del (DEL) | VAF 268/386 reads (69%) | catalogued as COSV60415119; called by mutect2, pindel, varscan2
- ROBO3 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs199762736, COSV67303090; called by muse, mutect2, varscan2
- RRM1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1251962665, COSV100331185; called by muse, mutect2
- SCG2 | c.411G>T p.L137F | Missense Mutation (SNP) | VAF 311/797 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); catalogued as COSV100544554; called by muse, mutect2, varscan2
- SCRIB | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1183074494, COSV100252237; called by muse, mutect2, varscan2
- SERPINI1 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 23/464 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV99854746; called by muse, mutect2
- SH2D3C | c.1331G>A p.R444H (on ENST00000314830 / NM_170600.3; = p.R287H on NM_005489.4) | Missense Mutation (SNP) | VAF 135/314 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1210425457, COSV59119065; called by muse, mutect2, varscan2
- SLC25A36 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs772118849, COSV100148926; called by muse, mutect2, varscan2
- SLC9A3 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 120/612 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs1382013692, COSV53799442; called by muse, mutect2, varscan2
- SNPH | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs772414070, COSV67870480; called by muse, mutect2
- SPG7 | c.376+2T>C p.X126_splice | Splice Site (SNP) | VAF 30/33 reads (91%) | catalogued as COSV99244419; called by muse, varscan2
- SPTBN5 | c.2860A>G p.S954G | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV100310376; called by muse, mutect2, varscan2
- SRGAP3 | c.2272C>T p.R758W | Missense Mutation (SNP) | VAF 76/311 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774033599, COSV100840605; called by muse, mutect2, varscan2
- TCF20 | c.5552A>G p.E1851G | Missense Mutation (SNP) | VAF 172/981 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100166118; called by muse, mutect2, varscan2
- TMEM199 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.347); catalogued as rs782430196, COSV99134646; called by muse, mutect2
- TRIM67 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs530421369, COSV64159468; called by muse, mutect2, varscan2
- TRPC6 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 308/565 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60262370; called by muse, mutect2, varscan2
- TRPM2 | c.4007G>A p.R1336H | Missense Mutation (SNP) | VAF 111/436 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs550041022, COSV55977723; called by muse, mutect2, varscan2
- UFSP2 | c.623dup p.N208Kfs*20 | Frame Shift Ins (INS) | VAF 98/260 reads (38%) | catalogued as rs1252058978; called by mutect2, varscan2
- VARS1 | c.2522C>T p.T841M | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.317); catalogued as rs765740371, COSV63304701; called by muse, mutect2
- VAV1 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 50/215 reads (23%) | catalogued as COSV100408490; called by muse, mutect2, varscan2
- VLDLR | c.1100G>A p.C367Y | Missense Mutation (SNP) | VAF 56/300 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV101173200; called by muse, mutect2, varscan2
- ZMYND8 | c.529G>A p.V177I (on ENST00000311275 / NM_001363741.2; = p.V197I on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/482 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); catalogued as COSV53695994; called by muse, mutect2
- ZNF462 | c.5770C>T p.R1924C | Missense Mutation (SNP) | VAF 15/421 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1002618193; called by muse, mutect2
- EIF4ENIF1 | c.6_12dup p.S5* | Nonsense Mutation (INS) | VAF 70/230 reads (30%) | called by mutect2, varscan2
- MAP3K5 | c.3668_3671dup p.T1225Efs*10 | Frame Shift Ins (INS) | VAF 67/153 reads (44%) | called by mutect2, pindel, varscan2
- PLPPR5 | c.598G>C p.V200L | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- SLC3A1 | c.187dup p.Q63Pfs*73 | Frame Shift Ins (INS) | VAF 18/141 reads (13%) | called by mutect2, pindel, varscan2
- ST6GALNAC3 | c.184T>C p.Y62H | Missense Mutation (SNP) | VAF 9/254 reads (4%) | PolyPhen benign (0.007); called by muse, mutect2
- ALDH5A1 | c.753A>G p.S251= | Silent (SNP) | VAF 118/544 reads (22%) | catalogued as COSV100708682; called by muse, mutect2, varscan2
- ATP10A | c.4173G>A p.P1391= | Silent (SNP) | VAF 20/262 reads (8%) | catalogued as rs543352421, COSV63517329; called by muse, mutect2
- C11orf87 | c.45G>A p.P15= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV100535624, COSV59358338; called by muse, varscan2
- C6orf118 | c.270C>T p.R90= | Silent (SNP) | VAF 195/321 reads (61%) | catalogued as rs200236975, COSV57814583, COSV57816797; called by muse, mutect2, varscan2
- COL4A5 | c.3117T>C p.G1039= | Silent (SNP) | VAF 11/226 reads (5%) | catalogued as COSV100086094; called by muse, mutect2
- ERG | c.1029C>T p.N343= (on ENST00000398919 / NM_001243428.1; = p.N319= on NM_004449.4) | Silent (SNP) | VAF 176/313 reads (56%) | catalogued as rs747955636, COSV99900945; called by muse, mutect2, varscan2
- FSIP2 | c.18786G>A p.K6262= | Silent (SNP) | VAF 115/266 reads (43%) | catalogued as rs1445180631, COSV100553489; called by muse, mutect2, varscan2
- IPO9 | c.2760G>A p.L920= | Silent (SNP) | VAF 18/550 reads (3%) | called by muse, mutect2
- JAG1 | c.1443C>T p.G481= | Silent (SNP) | VAF 43/419 reads (10%) | catalogued as rs879921003, COSV99652270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCND2 | c.753G>A p.A251= | Silent (SNP) | VAF 209/429 reads (49%) | catalogued as rs1374267694, COSV58572523, COSV58572595; called by muse, mutect2, varscan2
- MAPT | c.861G>A p.P287= (on ENST00000262410 / NM_001377265.1; = p.P212= on NM_016835.4) | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as rs545400674; called by muse, mutect2
- OR2A4 | c.37C>T p.L13= | Silent (SNP) | VAF 16/385 reads (4%) | catalogued as COSV100199590; called by muse, mutect2
- PDPN | c.45G>T p.S15= (on ENST00000621990; = p.S91= on NM_006474.4) | Silent (SNP) | VAF 9/167 reads (5%) | catalogued as COSV99611125, COSV99611847; called by muse, mutect2
- PLEKHG4B | c.1446G>A p.L482= (on ENST00000283426; = p.L838= on NM_052909.5) | Silent (SNP) | VAF 53/277 reads (19%) | catalogued as COSV99359576; called by muse, mutect2, varscan2
- PYROXD2 | c.1032G>A p.P344= | Silent (SNP) | VAF 51/314 reads (16%) | catalogued as rs1206731781, COSV65329517; called by muse, mutect2, varscan2
- RXFP3 | c.1122C>T p.S374= | Silent (SNP) | VAF 33/682 reads (5%) | catalogued as COSV100347148; called by muse, mutect2
- SALL3 | c.1956G>T p.L652= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV101609900, COSV73306197; called by muse, mutect2
- SF3B6 | c.6G>A p.A2= | Silent (SNP) | VAF 195/579 reads (34%) | catalogued as rs1208650632, COSV99272510; called by muse, mutect2, varscan2
- SHOX | c.255C>T p.F85= | Silent (SNP) | VAF 14/428 reads (3%) | catalogued as COSV61861691; called by muse, mutect2
- SLC1A5 | c.486C>T p.I162= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV101314745; called by muse, mutect2
- SPTBN1 | c.126G>C p.R42= | Silent (SNP) | VAF 63/303 reads (21%) | catalogued as COSV100776850; called by muse, mutect2, varscan2
- VCAM1 | c.1131C>T p.N377= | Silent (SNP) | VAF 47/534 reads (9%) | catalogued as rs372051353; called by muse, mutect2
- ZKSCAN3 | c.483C>T p.S161= | Silent (SNP) | VAF 99/298 reads (33%) | catalogued as COSV99356679; called by muse, mutect2, varscan2
- ZNF454 | c.558C>A p.V186= | Silent (SNP) | VAF 24/312 reads (8%) | catalogued as COSV100194483; called by muse, mutect2
- ZNFX1 | c.2205C>T p.T735= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV100870686; called by muse, mutect2
- KIR3DX1 | n.284A>G | RNA (SNP) | VAF 41/170 reads (24%) | catalogued as COSV99682779; called by muse, mutect2, varscan2
- LINC02870 | n.305C>T | RNA (SNP) | VAF 51/1070 reads (5%) | catalogued as rs201692866; called by muse, mutect2
